CCDI case PBBXRU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/0cac3659-5409-4dda-84a5-eb97620b21c8

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,624 days).

Biospecimens (3 samples)
- Sample 0DK5H3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK5H9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK5HO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
